Gene-level copy-number profile of tumor specimen TCGA-B6-A0IE-01A from TCGA case TCGA-B6-A0IE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 38.3 years (13,982 days).
Specimen TCGA-B6-A0IE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.0716b4fb-1209-4a73-b14f-245d7277c7f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0IE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93803ef8-98bd-4372-a3ce-c26dcf5d19d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 9,232; copy number 2: 37,851; copy number 3: 9,298; copy number 4: 1,412; copy number 5: 481; copy number 6: 1,055; copy number 7: 181; copy number 9: 56; copy number 11: 179.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0IE-01A-11D-A036-01): tumor purity 0.59, ploidy 2.15, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:113,738,106–115,632,992, 25 genes (within-gene range 0–1): AC093240.1, KCNN2, RN7SKP89, AC010230.1, LINC01957, AC094104.2, AC094104.1, TRIM36, TRIM36-IT1, AC008494.2, PGGT1B, AC008494.3, AC008494.1, CCDC112, HMGN1P15, CTNNA1P1, AK3P4, AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1, TMED7.
- chr5:136,376,348–136,763,409, 5 genes: AC063980.1, HSPD1P18, HNRNPA1P13, AC112178.1, AC109439.1.
- chr5:170,747,047–170,814,047, 2 genes: AC008514.1, GABRP.
- chr17:11,241,213–12,143,830, 11 genes (within-gene range 0–1): SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1.
- chr17:22,090,743–22,706,703, 28 genes: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,952 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:65,377,592–145,066,685, 1,252 genes, copy number 5–6 (broad region; genes not listed).
- chr20:35,172,072–35,699,355, 30 genes, copy number 5 (within-gene range 1–5): PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1.
- chr20:35,771,974–38,772,520, 92 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:39,655,325–39,663,552, 1 gene, copy number 6: AL132981.1.
- chr20:41,402,083–41,618,384, 1 gene, copy number 7 (within-gene range 2–7): CHD6.
- chr20:41,485,571–64,313,132, 576 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,280. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
